Somatic mutation profile of tumor specimen TCGA-GR-7353-01A (aliquot TCGA-GR-7353-01A-11D-2210-10) from TCGA case TCGA-GR-7353, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 36.5 years (13,317 days).
Specimen TCGA-GR-7353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae0a72e5-57a6-4239-b3a5-7380dc9ad20f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GR-7353-10A (Blood Derived Normal), aliquot TCGA-GR-7353-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5051c820-ad63-4db7-adef-30bd4cd5790c

The open-access MAF lists 137 somatic variants for this specimen: 101 protein-altering or splice-affecting, 35 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 35, Nonsense Mutation 8, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 3, Splice Site 2, In Frame Del 2, In Frame Ins 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1057519879, COSV62563048, COSV62563174, COSV62563707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNS | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746307931, CM980460; ClinVar: pathogenic; called by muse, varscan2
- MAP2K1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs727504317, CM076269, COSV61068427, COSV61072298; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH9A1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1489054379; called by muse, mutect2, varscan2
- AVPR1B | c.820C>G p.R274G | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781919125; called by muse, mutect2, varscan2
- BIRC3 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 89/476 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99679624; called by muse, varscan2
- CCDC39 | c.1995A>G p.I665M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56482378; called by muse, mutect2
- CNTLN | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs779499136; called by muse, mutect2, varscan2
- CYP24A1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.197); catalogued as rs769905811; called by muse, mutect2, varscan2
- DALRD3 | c.1370C>T p.P457L (on ENST00000341949 / NM_001009996.3; = p.P290L on NM_018114.5) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs766222473, COSV100482958; called by muse, mutect2, varscan2
- FAM135B | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50526251; called by muse, mutect2, varscan2
- FAM32A | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV99655300; called by muse, mutect2, varscan2
- GSDME | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs781204290; called by muse, mutect2, varscan2
- H1-4 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs766549245, COSV56802372, COSV99175186; called by muse, mutect2, varscan2
- IGHG2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs1467729776; called by muse, varscan2
- IGHG2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1439659583; called by muse, varscan2
- IGHV1-69 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs11558006; called by muse, varscan2
- IGHV3-30 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 170/668 reads (25%) | catalogued as rs571951651; called by muse, varscan2
- IGHV3-30 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 151/909 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs1280778312; called by muse, varscan2
- IGSF9B | c.3223G>T p.G1075C | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs527279278, COSV58073854; called by muse, varscan2
- MAD2L1BP | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV64665464; called by muse, mutect2, varscan2
- MTHFR | c.917G>A p.C306Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs925312071; called by muse, mutect2, varscan2
- MYBPC2 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374005339; called by muse, mutect2
- NDST3 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 56/115 reads (49%) | catalogued as COSV56627188; called by muse, mutect2, varscan2
- NETO1 | c.229A>G p.R77G | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.241); catalogued as COSV55007429; called by muse, mutect2, varscan2
- PANX2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs767235603; called by muse, mutect2, varscan2
- PCDHGA11 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.358); catalogued as rs760216287, COSV99547946; called by muse, mutect2, varscan2
- PPP1R3A | c.1510G>C p.G504R | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99493087; called by muse, mutect2, varscan2
- PRKN | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV100626915; called by muse, mutect2, varscan2
- PTH1R | c.424+1G>C p.X142_splice | Splice Site (SNP) | VAF 45/136 reads (33%) | catalogued as rs201472450; called by muse, mutect2, varscan2
- SCAMP5 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs771308149, COSV62643735; called by muse, mutect2, varscan2
- SLC35F1 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs769923966, COSV64501852; called by muse, mutect2, varscan2
- SPAG16 | c.1647del p.R550Gfs*11 | Frame Shift Del (DEL) | VAF 70/178 reads (39%) | catalogued as COSV100533878; called by mutect2, pindel, varscan2
- SYNGR4 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as rs756716248; called by muse, mutect2, varscan2
- TRPV3 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755746854; called by muse, mutect2, varscan2
- TTN | c.12137C>A p.P4046H (on ENST00000591111; = p.P4000H on NM_003319.4) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | catalogued as COSV100600183; called by muse, mutect2, varscan2
- WRAP73 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762956397; called by muse, mutect2
- ZNF544 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs74863048; called by muse, mutect2, varscan2
- ZNF676 | c.385G>T p.G129C (on ENST00000650058; = p.G97C on NM_001001411.3) | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.876); catalogued as COSV68092158; called by muse, mutect2, varscan2
- ACOT4 | c.528C>A p.S176R | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADCK1 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATXN2 | c.3272C>G p.S1091* (on ENST00000550104; = p.S931* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 49/160 reads (31%) | called by muse, mutect2, varscan2
- BTG2 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CAMKMT | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, varscan2
- CCR2 | c.208T>G p.C70G | Missense Mutation (SNP) | VAF 131/334 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CHD1L | c.2377A>C p.K793Q | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHD8 | c.5419del p.Y1807Ifs*29 (on ENST00000646647 / NM_001170629.2; = p.Y1528Ifs*29 on NM_020920.4) | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- CNOT4 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP5 | c.649G>T p.V217F | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPSF1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CREBBP | c.4411A>G p.I1471V | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CREBBP | c.3352C>T p.Q1118* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- CSMD3 | c.6263C>T p.S2088F (on ENST00000297405 / NM_001363185.1; = p.S1984F on NM_052900.3) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DMBT1 | c.2363T>G p.F788C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSC1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DSG1 | c.1462A>C p.N488H | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EBF1 | c.150_157dup p.H53Pfs*71 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | called by mutect2, varscan2
- EIF3A | c.1370_1381del p.S457_P460del | In Frame Del (DEL) | VAF 40/169 reads (24%) | called by mutect2, pindel, varscan2
- EIF3E | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAM186B | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- FAT3 | c.3484C>A p.P1162T | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FPR3 | c.478A>T p.N160Y | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FZD2 | c.1422del p.I475Sfs*21 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel, varscan2
- GGA3 | c.1985_1988dup p.E663Dfs*7 (on ENST00000537686 / NM_138619.4; = p.E630Dfs*7 on NM_014001.5) | Frame Shift Ins (INS) | VAF 54/183 reads (30%) | called by mutect2, pindel, varscan2
- GLIS3 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- HMG20A | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2
- HNRNPL | c.882T>A p.G294= | Splice Region (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- IGHG2 | c.536_551del p.F179Sfs*10 | Frame Shift Del (DEL) | VAF 84/226 reads (37%) | called by pindel, varscan2
- IGHG2 | c.336_338del p.P113del | In Frame Del (DEL) | VAF 38/135 reads (28%) | called by pindel, varscan2
- IGHM | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.12); called by muse, varscan2
- IGHM | c.373_374insACAACCCCC p.G125delinsDNPR | In Frame Ins (INS) | VAF 22/58 reads (38%) | called by pindel, varscan2
- IGHM | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 89/133 reads (67%) | SIFT tolerated (0.15); called by muse, mutect2, varscan2
- IGHV4-31 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 106/493 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, varscan2
- ITPRID1 | c.1845G>C p.E615D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KDM2A | c.3428A>C p.D1143A | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- METTL25 | c.750T>G p.N250K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5B | c.11545T>G p.S3849A | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PCDHA13 | c.729C>G p.Y243* | Nonsense Mutation (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- PCLO | c.14618A>C p.E4873A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZD4 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGGT1B | c.721dup p.S241Ffs*25 | Frame Shift Ins (INS) | VAF 105/403 reads (26%) | called by mutect2, pindel, varscan2
- PIAS1 | c.1742T>C p.F581S | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2
- PLIN3 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIMS4 | c.350-2A>T p.X117_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- RPS13 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- SIN3B | c.2862G>A p.K954= | Splice Region (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- SLC44A3 | c.1085T>C p.V362A (on ENST00000271227 / NM_001114106.3; = p.V314A on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SLC6A15 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLITRK3 | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SRSF1 | c.378T>C p.S126= | Splice Region (SNP) | VAF 51/160 reads (32%) | called by muse, mutect2, varscan2
- TDP1 | c.1414T>C p.W472R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TELO2 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TRPM5 | c.1910G>T p.W637L | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TSHZ1 | c.934T>C p.C312R (on ENST00000580243 / NM_001308210.2; = p.C267R on NM_005786.6) | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP25 | c.821T>G p.L274* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- USP25 | c.822A>C p.L274F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP43 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- VPS13C | c.3742C>A p.P1248T (on ENST00000644861 / NM_020821.3; = p.P1205T on NM_017684.5) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZNF281 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 97/206 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF300 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- ZNF658 | c.1757A>T p.N586I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- ADAMTS6 | c.492G>A p.E164= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs751941279; called by muse, mutect2
- ASB6 | c.330C>T p.A110= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs144137235; called by muse, mutect2, varscan2
- BIRC3 | c.57G>A p.T19= | Silent (SNP) | VAF 86/410 reads (21%) | catalogued as rs777921236; called by muse, varscan2
- BIRC3 | c.744T>A p.S248= | Silent (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- CDRT1 | c.600T>G p.T200= | Silent (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
- CFAP221 | c.1500A>G p.K500= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs770389733; called by muse, mutect2, varscan2
- DBX2 | c.285C>T p.A95= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1055830362; called by muse, mutect2, varscan2
- DNA2 | c.2793A>G p.G931= | Silent (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- EVI5 | c.117G>C p.S39= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs140717428; called by muse, mutect2, varscan2
- FAT3 | c.3369G>A p.R1123= | Silent (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- GNA14 | c.276G>A p.T92= | Silent (SNP) | VAF 101/295 reads (34%) | catalogued as rs781490674, COSV59029091; called by muse, mutect2, varscan2
- GPR151 | c.795C>T p.P265= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs751298465; called by muse, mutect2, varscan2
- HIP1 | c.2928C>T p.I976= | Silent (SNP) | VAF 65/288 reads (23%) | catalogued as COSV61184645; called by muse, mutect2, varscan2
- HNRNPA1 | c.723G>A p.G241= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs1301550225; called by muse, mutect2, varscan2
- IGHG2 | c.627C>A p.A209= | Silent (SNP) | VAF 53/223 reads (24%) | called by muse, varscan2
- IGHG2 | c.84G>C p.L28= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs777820776; called by muse, varscan2
- IGHM | c.1293G>A p.K431= | Silent (SNP) | VAF 100/154 reads (65%) | called by muse, mutect2, varscan2
- IGHM | c.816C>T p.N272= | Silent (SNP) | VAF 148/240 reads (62%) | called by muse, varscan2
- IGHM | c.510G>A p.E170= | Silent (SNP) | VAF 134/226 reads (59%) | catalogued as rs563693449; called by muse, varscan2
- IGHV4-31 | c.69G>T p.L23= | Silent (SNP) | VAF 94/462 reads (20%) | catalogued as rs1162042009; called by muse, varscan2
- IGLV4-60 | c.357C>T p.N119= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV101135198; called by muse, mutect2, varscan2
- KIF13A | c.2193C>T p.I731= | Silent (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- KLC1 | c.1434C>T p.G478= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- LARP4B | c.402T>C p.Y134= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- MLLT6 | c.753G>A p.K251= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- MYO3B | c.1224T>C p.N408= | Silent (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- NOL8 | c.2136T>G p.S712= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- PTPN4 | c.2724T>A p.I908= | Silent (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- RSPH1 | c.132C>T p.Y44= | Silent (SNP) | VAF 56/223 reads (25%) | catalogued as rs772915587, COSV52319867; called by muse, mutect2, varscan2
- SALL4 | c.1767C>T p.T589= | Silent (SNP) | VAF 49/158 reads (31%) | catalogued as rs201329321, COSV53853039; called by muse, mutect2, varscan2
- SEC14L5 | c.1884C>T p.L628= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as rs1302785770; called by muse, mutect2, varscan2
- SF3B4 | c.954C>T p.G318= | Silent (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- TRDMT1 | c.24G>A p.E8= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs757797486; called by muse, varscan2
- ZNF697 | c.438T>C p.H146= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs374393078; called by muse, mutect2, varscan2
- ZNF91 | c.1266T>A p.T422= | Silent (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331268 C>A | 5'Flank (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
